Gene-level copy-number profile of tumor specimen TCGA-D7-A6EV-01A from TCGA case TCGA-D7-A6EV, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 71.8 years (26,226 days).
Specimen TCGA-D7-A6EV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.34b085d5-20fe-42e1-a107-5820e5bfba2b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-A6EV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dd2ea9f2-a5ac-4aac-9915-74b17b7555bd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 5,676; copy number 2: 33,611; copy number 3: 12,555; copy number 4: 4,505; copy number 5: 1,874; copy number 6: 652; copy number 7: 506; copy number 8: 1; copy number 9: 88; copy number 10: 125; copy number 11: 62; copy number 12: 77; copy number 13: 64; copy number 15: 5; copy number 17: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-A6EV-01A-11D-A31K-01): tumor purity 0.59, ploidy 2.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,528,861–59,529,251, 1 gene: NDUFB4P2.
- chr16:78,550,739–78,553,296, 1 gene: AC046158.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,465 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,693,124–11,262,551, 116 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:153,533,603–154,993,111, 90 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr2:66,696,190–66,703,252, 1 gene, copy number 5: LINC01797.
- chr2:225,698,254–230,068,993, 60 genes, copy number 5–9 (within-gene range 5–16): AC016717.1, AC016717.2, AC016717.3, AC068138.1, AC062015.1, MIR5702, IRS1, AC010735.2, AC010735.1, RHBDD1, AC073149.1, COL4A4, COL4A3, MFF-DT, MFF, TM4SF20, SCYGR1, MIR5703, AGFG1, SCYGR9, SCYGR2, SCYGR10, C2orf83, SCYGR3, AC064853.1, SCYGR4, SCYGR5, SLC19A3, SCYGR6, SCYGR7, SCYGR8, RNA5SP121, SNRPGP8, AC073065.1, CCL20, TDGF1P2, DAW1, AC073065.2, SPHKAP, RNU6-624P, SNF8P1, AC009410.1, LINC01807, AC012070.1, RPL7L1P10, PID1, RPL17P14, RN7SKP283, DNER, AC008273.1, RNU7-9P, AC007559.1, TRIP12, RNU6-613P, FBXO36, RNU6-964P, FBXO36-IT1, RNU6-1027P, SLC16A14, RNY4P19.
- chr3:11,745–54,346, 2 genes, copy number 6: LINC01986, AC066595.1.
- chr6:12,582,915–12,585,404, 1 gene, copy number 8: LINC02530.
- chr7:91,030,149–94,077,157, 56 genes, copy number 12: AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2.
- chr7:94,311,138–94,347,063, 1 gene, copy number 12 (within-gene range 4–12): AC002074.2.
- chr7:98,252,379–101,629,296, 158 genes, copy number 5–13 (within-gene range 4–13) (broad region; genes not listed).
- chr7:102,264,706–107,643,023, 116 genes, copy number 10–15 (broad region; genes not listed).
- chr7:117,262,918–118,951,259, 20 genes, copy number 12: AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, AC002465.1, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1, AC003084.1, LSM8, ANKRD7, AC002529.1, GTF3AP6, AC092098.1.
- chr7:132,648,794–134,066,589, 14 genes, copy number 10 (within-gene range 3–10): FLJ40288, AC009365.1, AC009365.2, CHCHD3, AC009365.3, AC008038.1, MIR3654, RNU6-92P, ST13P7, EXOC4, MIR6133, AC083875.1, COX5BP3, RPS3AP27.
- chr7:139,523,685–139,544,985, 1 gene, copy number 9 (within-gene range 3–9): CLEC2L.
- chr7:140,282,465–141,052,409, 21 genes, copy number 11: AC005377.1, PPP1R2P6, SLC37A3, RNA5SP247, RNA5SP248, RAB19, AC069335.1, MKRN1, DENND2A, Y_RNA, AC006452.1, RN7SL771P, ADCK2, NDUFB2, NDUFB2-AS1, BRAF, RNU6-85P, AC006006.1, CCT4P1, MRPS33, RNU4-74P.
- chr7:141,173,043–141,173,216, 1 gene, copy number 11: AC006362.1.
- chr8:83,099,976–137,425,021, 754 genes, copy number 5–6 (broad region; genes not listed).
- chr8:139,460,062–145,066,685, 210 genes, copy number 5 (broad region; genes not listed).
- chr10:31,318,495–31,529,814, 1 gene, copy number 17 (within-gene range 2–17): ZEB1.
- chr10:31,602,862–33,917,804, 43 genes, copy number 13–17: AL161935.1, AL161935.3, AL161935.2, MACORIS, Y_RNA, ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13, AL158834.2, EPC1, AL158834.1, AL391839.2, AL391839.1, RNU6-1244P, AL391839.3, CCDC7, C1DP1, ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, AL353600.2, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629.
- chr11:69,425,690–97,259,987, 633 genes, copy number 5–9 (broad region; genes not listed).
- chr11:100,336,856–115,843,146, 291 genes, copy number 5 (broad region; genes not listed).
- chr11:131,770,795–131,984,661, 3 genes, copy number 6: AP004372.1, AP000844.2, AP000844.1.
- chr13:104,814,327–114,337,626, 162 genes, copy number 5 (broad region; genes not listed).
- chr17:35,918,066–36,017,972, 11 genes, copy number 9 (within-gene range 2–9): RDM1, LYZL6, AC244100.1, CCL16, CCL14, AC244100.2, CCL15-CCL14, CCL15, AC244100.3, AC244100.4, CCL23.
- chr17:37,406,886–37,479,725, 1 gene, copy number 7 (within-gene range 3–7): TADA2A.
- chr17:37,454,171–38,605,952, 31 genes, copy number 7: AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA, MRPL45, GPR179, SOCS7, ARHGAP23, AC244153.1, SRCIN1, AC006449.1.
- chr18:9,102,630–12,304,194, 103 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr18:20,946,906–24,162,211, 72 genes, copy number 7 (broad region; genes not listed).
- chr18:24,170,505–24,179,295, 2 genes, copy number 7: RNA5SP452, Metazoa_SRP.
- chr20:25,669,857–31,723,989, 83 genes, copy number 7 (broad region; genes not listed).
- chr20:47,478,214–64,313,132, 407 genes, copy number 5–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,255. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
